CGCI case BLGSP-71-30-00657 — Burkitt Lymphoma Genome Sequencing Project (CGCI-BLGSP)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Mature B-Cell Lymphomas; Primary site: Hematopoietic and reticuloendothelial systems. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/d51906c4-47f3-4c18-95e8-3df608b4f9f4

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Age at index: 77 years; Vital status: Dead; Days to death: 695 days (1.9 years); Cause of death: Cancer Related.

Diagnoses (2)
1. Burkitt lymphoma, NOS (Includes all variants) (the primary disease): ICD-O-3 morphology code: 9687/3; Tissue or organ of origin: Hematopoietic system, NOS; Site of resection or biopsy: Lymph nodes of inguinal region or leg; Classification of tumor: primary; Age at diagnosis: 77.1 years (28,166 days); Year of diagnosis: 2013; Method of diagnosis: Incisional Biopsy; Ann Arbor pathologic stage: Stage IV; Ann Arbor B symptoms: Yes; Prior malignancy: yes; Prior treatment: No; Days to last follow up: 672 days (1.8 years); Ann Arbor extranodal involvement: Yes; Burkitt lymphoma clinical variant: Sporadic, adult; Max tumor bulk site: Inguinal; Sites of involvement: Parotid gland.
   Pathology details: Lymph node involved site: Parotid.
   Pathology details: Lymph node involved site: Iliac, NOS.
   Pathology details: Lymph node involved site: Hilar.
   Pathology details: Lymph node involved site: Inguinal.
   Pathology details: Lymph node involved site: Mediastinal.
   Pathology details: Bone marrow malignant cells: Yes; Lymph node involved site: Axillary; Lymph nodes positive: 1; Lymph nodes tested: 1; Tumor largest dimension diameter: 8 cm.
   Treatment given: Treatment type: Chemotherapy; Initial disease status: Initial Diagnosis; Regimen or line of therapy: EPOCH-R; Days to treatment start: 14 days; Days to treatment end: 130 days; Number of cycles: 5; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Chemotherapy; Therapeutic agents: Cyclophosphamide + Doxorubicin + Etoposide + Prednisone + Rituximab + Vincristine; Initial disease status: Initial Diagnosis; Days to treatment start: 14 days; Days to treatment end: 130 days; Number of cycles: 5; Treatment outcome: Complete Response.
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Treatment intent type: Adjuvant; Treatment outcome: Complete Response.
   Recorded as not given: neoadjuvant treatment (type not reported), for initial diagnosis; adjuvant Radiation Therapy, NOS.
2. Tumor, NOS: Tissue or organ of origin: Bone, NOS; Classification of tumor: Synchronous primary; Age at diagnosis: 78.9 years (28,808 days); Days to diagnosis: 642 days (1.8 years).
   Treatment given: Treatment type: Pharmaceutical Therapy, NOS; Initial disease status: Initial Diagnosis.
   Recorded as not given: Radiation Therapy, NOS, for initial diagnosis; Surgery, NOS, for initial diagnosis.

Follow-up (2 entries)
- Days to follow up: 0 days; ECOG performance status: 2.
- Days to follow up: 672 days (1.8 years); Disease response: Tumor Free.

Molecular and laboratory tests
- BCL2 (FISH): Normal.
- BCL2 (IHC): Negative.
- BCL6 (IHC): Positive; Specialized molecular test: BCL6 > 30%.
- CD10 (IHC): Positive; Specialized molecular test: CD10 > 30%.
- CD20 (IHC): Positive.
- CD3 (IHC): Negative.
- Ki67 (IHC): Positive; Specialized molecular test: Ki-67 > 90%.
- MYC translocation (FISH): Abnormal, NOS.
- Lactate Dehydrogenase 368 [Blood test normal range upper: 240].

Other clinical attributes
- Day 0: Weight: 55 kg; Height: 158.7 cm; BMI: 21.8.
- Day 0: Comorbidities: ITP.
- Day 0: Risk factor treatment: Yes.
- Day 0: Immunosuppressive treatment type: Other; Risk factor treatment: Yes.

Biospecimens (3 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample BLGSP-71-30-00657-01A: Sample type: FFPE Scrolls; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Other; Preservation method: FFPE; Days to sample procurement: 0 days; Method of sample procurement: Incisional Biopsy; Tissue collection type: Retrospective.
- Sample BLGSP-71-30-00657-01B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Biospecimen anatomic site: Lymph Node.
- Sample BLGSP-71-30-00657-01Z: Sample type: Tumor; Tissue type: Tumor.
  Slide BLGSP-71-30-00657-01-Ki67: Tissue microarray coordinates: A4,B4.
  Slide BLGSP-71-30-00657-01-EBER: Tissue microarray coordinates: A4,B4.
  Slide BLGSP-71-30-00657-01-BCL6: Tissue microarray coordinates: A4,B4.
  Slide BLGSP-71-30-00657-01-CD20: Tissue microarray coordinates: A4,B4.
  Slide BLGSP-71-30-00657-01-BCL2: Tissue microarray coordinates: A4,B4.
  Slide BLGSP-71-30-00657-01-CD10: Tissue microarray coordinates: A4,B4.
  Slide BLGSP-71-30-00657-01-CD3: Tissue microarray coordinates: A4,B4.

Additional fields from the legacy TCGA clinical forms (Biospecimen Core Resource XML)
- Enrollment form: Prospective collection: No; Retrospective collection: Yes; History neoadjuvant treatment: No; Tumor status: Tumor free; Treatment outcome first course: Complete Remission/Response; Lost to follow-up: No; New tumor event diagnosis indicator: Yes.
- History of disease: History immunological disease other: ITP; History immunosuppressive prescription other: Splenectomy, Prednisone.
- Primary pathology: Histologic diagnosis: Burkitt lymphoma (BL), classic morphology; Extranodal site involvement: 1; Lymph nodes examined: Yes; Bone marrow sample histology: Discordant Histology.
- Primary pathology, Lymph node involvement sites: Lymph node involvement site: Iliac.
- Primary pathology, Extranodal involvement sites: Extranodal involvement site: Parotid Gland.
- Primary pathology, Pos lymph node locations: Pos lymph node location: Other Location, specify.
- Stage record, Ann arbor: B symptoms present indicator: Yes.
- Tests performed: LDH level: 368; Immunophenotypic analysis method: Immunohistochemistry.
- Tests performed, Genetic testing results, Genetic testing result 2: Immunophenotypic analysis tested: CD20.
- Tests performed, Genetic testing results, Genetic testing result 5: Immunophenotypic analysis tested: CD3.
- Tests performed, Genetic testing results, Genetic testing result 6: Immunophenotypic analysis tested: BCL2.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 1: Genetic abnormality tested: C-myc.
- Tests performed, Genetic abnormalities, Genetic abnormality testing result 2: Genetic abnormality tested: BCL2.
- New tumor event: New tumor event type: New Primary Tumor; New tumor event site: Bone; New tumor event diagnosis evidence: Biopsy with Histologic Confirmation; New tumor event surgery: No; New tumor event radiation treatment: No; New tumor event pharmaceutical treatment: Yes.
- Treatments, Treatment: Therapy regimen: Initial; Chemo end reporting period: Yes; Pharmaceutical regimen: Other Pharmaceutical Regimen (please specify); Pharmaceutical regimen other: Cyclophosphamide and Rituximab x1, EPOCH-R; Pharma adjuvant cycles count: 5.

Additional fields from the CGCI biospecimen supplement workbook CGCI-BLGSP_biospecimenSupplementSpreadsheet_TWIST_20220304.xlsx (sheet Sheet1), for sample BLGSP-71-30-00657-01A-01E-0001-01:
- % tumour: 90
